Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A3HT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A3HT-01A (Primary Tumor).

Procurement Date: , Laterality:

Path Report: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 1 x 2 x 2 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Well differentiated

Tumor extent: Not specified

Lymph nodes: 0/9 positive for metastasis (Regional 0/9)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Gross Description:

ICA-0-3

Microscopic Description:

Carcinoma, squamous cell 8070/3

Diagnosis Details:

Site: cervix, NOS C53.9

hw
12/1/11

ICDPA Discrepancy		X
hw	12/1/11	12/1/11

Source: NCI Genomic Data Commons file fe3c1301-31f4-4ce2-9db8-594f90e02367 (TCGA-EA-A3HT.ADE9CA35-C9F2-417E-8B27-59ACC7E1AE32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).